Somatic mutation profile of tumor specimen TCGA-94-8491-01A (aliquot TCGA-94-8491-01A-11D-2323-08) from TCGA case TCGA-94-8491, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 73.1 years (26,698 days).
Specimen TCGA-94-8491-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74b8acb0-4339-480c-bcf2-6f74a24f5488.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-94-8491-10A (Blood Derived Normal), aliquot TCGA-94-8491-10A-01D-2323-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6528324d-7245-4c1f-881a-70c02904cb52

The open-access MAF lists 574 somatic variants for this specimen: 443 protein-altering or splice-affecting, 121 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 371, Silent 121, Nonsense Mutation 33, Frame Shift Del 18, Splice Site 12, RNA 4, Splice Region 3, 3'UTR 3, Frame Shift Ins 2, Intron 2, In Frame Del 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 14/42 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB8 | c.701C>T p.S234F (on ENST00000297504 / NM_001282291.2; = p.S217F on NM_007188.5) | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV99874538; called by muse, mutect2, varscan2
- ABCC10 | c.3244C>T p.Q1082* (on ENST00000372530 / NM_001198934.2; = p.Q1054* on NM_033450.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/96 reads (9%) | catalogued as rs1333932782, COSV99767415; called by muse, mutect2
- ABCC11 | c.689C>G p.T230R | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100750854; called by muse, mutect2, varscan2
- ABCD2 | c.619G>T p.D207Y | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100429562; called by muse, mutect2, varscan2
- ABCF1 | c.763A>C p.K255Q | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as rs1189704956, COSV100400885; called by muse, mutect2, varscan2
- AC006059.2 | c.657G>T p.M219I | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV100045628; called by muse, mutect2, varscan2
- AC006059.2 | c.656T>A p.M219K | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as COSV100045630; called by muse, mutect2, varscan2
- AC008397.2 | c.270T>G p.C90W | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.312); catalogued as COSV99441831; called by muse, mutect2, varscan2
- AC008763.3 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 12/39 reads (31%) | catalogued as rs1192760960, COSV100365387; called by muse, mutect2, varscan2
- ACADM | c.119-2A>G p.X40_splice | Splice Site (SNP) | VAF 37/161 reads (23%) | catalogued as rs1376804614, COSV100897699; called by muse, mutect2, varscan2
- ACBD5 | c.265G>A p.G89R (on ENST00000375888 / NM_001352568.1; = p.G91R on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101022563; called by muse, mutect2, varscan2
- ACKR3 | c.836T>C p.I279T | Missense Mutation (SNP) | VAF 11/187 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.062); catalogued as COSV99799627; called by muse, mutect2
- ADAM28 | c.1979C>T p.S660L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV99063134, COSV99738886; called by muse, mutect2, varscan2
- ADAMTS5 | c.2537G>A p.R846H | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs762673375, COSV53186165; called by muse, mutect2
- ADCY5 | c.3721G>C p.V1241L | Missense Mutation (SNP) | VAF 24/281 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV100567858; called by muse, mutect2
- AGTR2 | c.904T>A p.F302I | Missense Mutation (SNP) | VAF 84/156 reads (54%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.456); catalogued as COSV100903592; called by muse, mutect2, varscan2
- AHNAK | c.4077T>G p.I1359M | Missense Mutation (SNP) | VAF 22/402 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV99947961; called by muse, mutect2
- AJUBA | c.17A>C p.E6A | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.407); catalogued as COSV99401047; called by muse, mutect2, varscan2
- AKAP11 | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99214018; called by muse, mutect2
- ALAS2 | c.508C>G p.R170G | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM095122, CM109565, COSV100238421, COSV100238671; called by muse, mutect2, varscan2
- ALDH9A1 | c.250G>T p.A84S | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV100699303; called by muse, mutect2, varscan2
- ALPK3 | c.4602A>T p.E1534D | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.88); PolyPhen benign (0.015); catalogued as COSV99361169; called by muse, mutect2
- AMDHD2 | c.532C>G p.L178V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV99565920; called by muse, mutect2
- AMER3 | c.152A>G p.K51R | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV100366659; called by muse, varscan2
- ANK1 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV99224615; called by muse, mutect2
- ANKS1B | c.1232G>T p.C411F | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV61355134; called by muse, mutect2
- AOAH | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.056); catalogued as COSV99333033; called by muse, mutect2, varscan2
- APAF1 | c.3190G>C p.D1064H (on ENST00000551964 / NM_181861.2; = p.D1010H on NM_001160.3) | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100244152, COSV59663687; called by muse, mutect2, varscan2
- APCS | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.28); catalogued as COSV99661349; called by muse, mutect2, varscan2
- AR | c.2149G>T p.V717F | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101018507; called by muse, mutect2, varscan2
- ARFRP1 | c.474C>G p.I158M | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.597); catalogued as COSV99423073; called by muse, mutect2, varscan2
- ARHGAP20 | c.2990A>T p.H997L | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV99504377; called by muse, mutect2, varscan2
- ARHGAP25 | c.558G>C p.E186D (on ENST00000409202 / NM_001007231.3; = p.E178D on NM_014882.3) | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as COSV99771671; called by muse, mutect2, varscan2
- ARID1B | c.6041C>G p.T2014R | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99269981; called by muse, mutect2
- ARL4C | c.367C>G p.L123V | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV100326990; called by muse, mutect2, varscan2
- ATP13A4 | c.2842+1G>A p.X948_splice | Splice Site (SNP) | VAF 9/156 reads (6%) | catalogued as COSV100710437; called by muse, mutect2
- ATP6V0A1 | c.2240C>A p.A747D (on ENST00000343619 / NM_001378531.1; = p.A741D on NM_005177.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99231159; called by muse, mutect2
- ATP6V1A | c.1195G>T p.E399* | Nonsense Mutation (SNP) | VAF 13/63 reads (21%) | catalogued as COSV99850186; called by muse, mutect2, varscan2
- AVPR2 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs782670498, COSV100509538, COSV100509545; called by muse, mutect2
- B9D2 | c.245C>A p.S82Y | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.184); catalogued as COSV99699162; called by muse, mutect2, varscan2
- BMT2 | c.500G>C p.R167T | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.528); catalogued as COSV51778557, COSV99774696; called by muse, mutect2, varscan2
- BPNT2 | c.487G>C p.E163Q | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.035); catalogued as COSV99389092; called by muse, mutect2
- BSN | c.10534G>A p.G3512R | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV99608773; called by muse, mutect2, varscan2
- BTK | c.975-1G>T p.X325_splice | Splice Site (SNP) | VAF 12/94 reads (13%) | catalogued as CS962668, COSV58121135; called by muse, mutect2, varscan2
- C6 | c.2285A>G p.E762G | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV99667235; called by muse, mutect2, varscan2
- C7orf31 | c.700G>C p.E234Q | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV52216865; called by muse, mutect2
- CA8 | c.773A>T p.K258M | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100527011; called by muse, mutect2, varscan2
- CACNA1B | c.201C>G p.N67K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99498028; called by muse, mutect2
- CACNA1E | c.5184C>G p.Y1728* | Nonsense Mutation (SNP) | VAF 12/318 reads (4%) | catalogued as COSV100703236, COSV62414973; called by muse, mutect2
- CACNA1S | c.602T>A p.L201Q | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100755098; called by muse, mutect2, varscan2
- CAMK1D | c.705G>T p.K235N | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.948); catalogued as COSV101123749; called by muse, mutect2, varscan2
- CASZ1 | c.1617C>A p.Y539* | Nonsense Mutation (SNP) | VAF 20/47 reads (43%) | catalogued as COSV100681554; called by muse, mutect2, varscan2
- CATSPERD | c.1255C>G p.P419A | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); catalogued as rs902497898, COSV100486842, COSV58467288; called by muse, mutect2, varscan2
- CCHCR1 | c.696G>C p.L232= | Splice Region (SNP) | VAF 181/366 reads (49%) | catalogued as COSV100885661; called by muse, mutect2, varscan2
- CCNL2 | c.233G>T p.R78L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV100784987; called by muse, mutect2, varscan2
- CD1B | c.602G>C p.R201T | Missense Mutation (SNP) | VAF 60/254 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV100939247, COSV63804274; called by muse, mutect2, varscan2
- CDC42BPA | c.2156A>T p.K719M | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV100505638; called by muse, mutect2, varscan2
- CDH13 | c.514A>G p.K172E | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.662); catalogued as COSV51883014; called by muse, mutect2, varscan2
- CDH6 | c.2047A>G p.I683V | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as COSV99419526; called by muse, mutect2, varscan2
- CENPF | c.3790T>G p.C1264G | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as rs1284384817, COSV100871731; called by muse, mutect2, varscan2
- CFAP61 | c.3346T>A p.L1116M | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99845327; called by muse, mutect2
- CIAO3 | c.1130T>A p.V377E | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99284933; called by muse, mutect2, varscan2
- CILP | c.718G>T p.G240W | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99973540; called by muse, mutect2, varscan2
- CIT | c.1903C>G p.Q635E | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV99949994; called by muse, mutect2, varscan2
- CKAP5 | c.2432A>T p.K811M | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100370901; called by muse, mutect2, varscan2
- CLEC11A | c.110A>T p.Q37L | Missense Mutation (SNP) | VAF 49/87 reads (56%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99141594; called by muse, mutect2, varscan2
- CLVS1 | c.598T>C p.S200P | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.155); catalogued as COSV100370141; called by muse, mutect2
- CMA1 | c.218C>A p.T73K | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.043); catalogued as COSV104376845; called by muse, mutect2
- CMYA5 | c.9692A>G p.D3231G | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV101484138; called by muse, mutect2, varscan2
- CNGA1 | c.1804G>C p.D602H | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV62053935; called by muse, mutect2
- CNTNAP4 | c.436C>G p.L146V | Missense Mutation (SNP) | VAF 33/245 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100270033, COSV100271875; called by muse, mutect2, varscan2
- CNTNAP4 | c.2836G>T p.E946* | Nonsense Mutation (SNP) | VAF 23/79 reads (29%) | catalogued as COSV100271880, COSV56676821; called by muse, mutect2, varscan2
- COL15A1 | c.2191C>G p.P731A | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.191); catalogued as COSV100897806; called by muse, mutect2, varscan2
- CPA6 | c.1088G>A p.G363E | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.996); catalogued as COSV99912525, COSV99913798; called by muse, mutect2
- CREB3L2 | c.1257C>A p.Y419* | Nonsense Mutation (SNP) | VAF 74/162 reads (46%) | catalogued as COSV100382028; called by muse, mutect2, varscan2
- CRY2 | c.261A>T p.K87N | Missense Mutation (SNP) | VAF 88/298 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV101314597; called by muse, mutect2, varscan2
- CRYGD | c.222C>A p.D74E | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as COSV99965326; called by muse, mutect2, varscan2
- CSF1 | c.539G>T p.S180I | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV100294605; called by muse, mutect2, varscan2
- CSMD2 | c.170C>A p.T57N | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as COSV99591415; called by muse, mutect2, varscan2
- CTIF | c.402G>T p.K134N | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.327); catalogued as COSV99837741; called by muse, mutect2, varscan2
- CTSG | c.149G>C p.G50A | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99361559; called by muse, mutect2
- CWH43 | c.70G>C p.D24H | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as COSV99893551; called by muse, mutect2, varscan2
- CYP7A1 | c.874C>A p.P292T | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100052426; called by muse, mutect2, varscan2
- DAB2 | c.1117C>T p.P373S | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as rs1221130006, COSV100298082; called by muse, mutect2, varscan2
- DACH2 | c.1082G>T p.R361I | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100913394; called by muse, mutect2, varscan2
- DAZAP2 | c.25A>G p.T9A | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.899); catalogued as COSV101199404; called by muse, mutect2
- DDR2 | c.2494T>G p.W832G | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100906619; called by muse, mutect2, varscan2
- DEPDC1B | c.1169A>T p.Q390L | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as COSV99409680; called by muse, mutect2
- DEPDC7 | c.465-1G>T p.X155_splice (on ENST00000241051 / NM_001077242.2; = p.X146_splice on NM_139160.2) | Splice Site (SNP) | VAF 5/33 reads (15%) | catalogued as COSV99572763; called by muse, mutect2, varscan2
- DHX15 | c.889G>T p.A297S | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.644); catalogued as COSV100391463; called by muse, mutect2, varscan2
- DHX34 | c.1615del p.D539Tfs*42 | Frame Shift Del (DEL) | VAF 7/53 reads (13%) | catalogued as COSV100169607; called by pindel, varscan2
- DHX38 | c.3038A>T p.N1013I | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99194347; called by muse, mutect2
- DIMT1 | c.432T>G p.H144Q | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.942); catalogued as COSV99551121; called by muse, mutect2, varscan2
- DLX2 | c.587T>G p.V196G | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99308589; called by muse, mutect2, varscan2
- DMWD | c.539T>G p.I180S | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV99537185; called by muse, mutect2, varscan2
- DNAI4 | c.2260G>T p.A754S | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.057); catalogued as COSV100925491; called by muse, mutect2, varscan2
- DNAJB7 | c.138C>G p.F46L | Missense Mutation (SNP) | VAF 64/169 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99344239; called by muse, mutect2, varscan2
- DNAJC11 | c.1525-1G>A p.X509_splice | Splice Site (SNP) | VAF 9/113 reads (8%) | catalogued as COSV99275770; called by muse, mutect2
- DNASE2B | c.326T>C p.I109T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as rs759311238, COSV101042104; called by muse, mutect2, varscan2
- DRD3 | c.779A>T p.Q260L | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.742); catalogued as COSV55678699, COSV99879500; called by muse, mutect2, varscan2
- DROSHA | c.2190G>T p.W730C | Missense Mutation (SNP) | VAF 89/303 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV100757651; called by muse, mutect2, varscan2
- DTX1 | c.1454G>A p.G485E | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55660626, COSV99921629; called by muse, mutect2, varscan2
- DYNC2H1 | c.2673A>G p.I891M | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.104); catalogued as rs1263008549, COSV100518791; called by muse, mutect2
- DZIP1L | c.1245G>T p.K415N | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV100551437; called by muse, mutect2, varscan2
- EDC3 | c.1114G>T p.V372F | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100166020; called by muse, mutect2
- EHD1 | c.264C>G p.I88M | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100277085; called by muse, mutect2, varscan2
- EIF3A | c.2512G>T p.E838* | Nonsense Mutation (SNP) | VAF 80/284 reads (28%) | catalogued as COSV100974653, COSV64963160; called by muse, mutect2, varscan2
- EIF4G1 | c.2381T>G p.L794R (on ENST00000346169 / NM_198241.3; = p.L599R on NM_004953.5) | Missense Mutation (SNP) | VAF 33/200 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100071946; called by muse, mutect2, varscan2
- ENPP4 | c.1105G>C p.D369H | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100320358; called by muse, mutect2
- EPHA1 | c.589G>A p.V197I | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1162100202, COSV99314154; called by muse, mutect2, varscan2
- EPHA3 | c.2143G>T p.D715Y | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60711854; called by muse, mutect2, varscan2
- ERICH3 | c.718C>A p.P240T | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV100444698; called by muse, mutect2, varscan2
- ERICH3 | c.86G>A p.R29K | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100444702; called by muse, mutect2, varscan2
- ERMARD | c.79C>G p.Q27E | Missense Mutation (SNP) | VAF 34/44 reads (77%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100824847; called by muse, mutect2, varscan2
- ESCO2 | c.1674G>T p.R558S | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100533298; called by muse, mutect2, varscan2
- ESYT3 | c.1277C>T p.S426L | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV67440932; called by muse, mutect2
- EVI5 | c.622A>G p.R208G | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100789685; called by muse, mutect2, varscan2
- EVI5 | c.277A>G p.N93D | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs1250287821, COSV100945363; called by muse, mutect2
- EXOC6B | c.256A>G p.R86G | Missense Mutation (SNP) | VAF 19/339 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV99724723; called by muse, mutect2
- EXT2 | c.1911C>A p.N637K (on ENST00000343631; = p.N670K on NM_000401.3) | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100640500, COSV100640627; called by muse, mutect2
- EYS | c.373del p.L125Ffs*6 | Frame Shift Del (DEL) | VAF 11/62 reads (18%) | catalogued as COSV60987728; called by mutect2, pindel, varscan2
- F10 | c.613G>T p.A205S | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV100979231; called by muse, mutect2, varscan2
- FAM135A | c.321G>T p.M107I (on ENST00000370479 / NM_001351599.1; = p.M64I on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV52047566, COSV99525949; called by muse, mutect2, varscan2
- FAM135B | c.1637G>T p.G546V | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as COSV99424807; called by muse, mutect2, varscan2
- FAM135B | c.176C>G p.S59* | Nonsense Mutation (SNP) | VAF 22/89 reads (25%) | catalogued as COSV99357416; called by muse, mutect2, varscan2
- FAM47A | c.1148G>T p.G383V | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.235); catalogued as COSV100649877; called by muse, mutect2, varscan2
- FAT3 | c.5396G>A p.R1799Q | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.074); catalogued as rs757999627, COSV99967065; called by muse, mutect2, varscan2
- FBXW11 | c.620C>G p.S207* | Nonsense Mutation (SNP) | VAF 25/53 reads (47%) | catalogued as COSV99440775; called by muse, mutect2, varscan2
- FKBP5 | c.1012G>C p.E338Q | Missense Mutation (SNP) | VAF 57/123 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV100616248; called by muse, mutect2, varscan2
- FKBPL | c.917C>A p.T306N | Missense Mutation (SNP) | VAF 124/241 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0.188); catalogued as COSV100913584, COSV64322731; called by muse, mutect2, varscan2
- FOXO1 | c.1792C>A p.L598I | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV101092026; called by muse, mutect2, varscan2
- FSTL5 | c.1957G>C p.A653P | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV100056727; called by muse, mutect2, varscan2
- FUT8 | c.475C>T p.H159Y | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.136); catalogued as COSV100651422; called by muse, mutect2, varscan2
- GAB4 | c.1354G>T p.V452F | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV101272009; called by muse, mutect2, varscan2
- GABRG1 | c.424A>T p.K142* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as COSV99778234; called by muse, mutect2, varscan2
- GANAB | c.2652G>C p.E884D | Missense Mutation (SNP) | VAF 21/460 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99642058; called by muse, mutect2
- GART | c.502T>A p.C168S | Missense Mutation (SNP) | VAF 26/388 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.711); catalogued as COSV100738201; called by muse, mutect2
- GBP5 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.584); catalogued as rs758404296, COSV100600116; called by muse, mutect2, varscan2
- GCC1 | c.2028G>T p.R676S | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as rs1157129672, COSV100365557; called by muse, mutect2, varscan2
- GCN1 | c.6976C>G p.L2326V | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.148); catalogued as COSV100325465, COSV56105642; called by muse, mutect2, varscan2
- GLIPR1L2 | c.244G>T p.V82L | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.926); catalogued as rs1361090008, COSV100248513, COSV100248642; called by muse, mutect2, varscan2
- GLUD1 | c.952A>G p.R318G | Missense Mutation (SNP) | VAF 68/246 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99518205; called by muse, mutect2, varscan2
- GNAI1 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63524948; called by muse, mutect2, varscan2
- GOLGA5 | c.1608G>C p.E536D | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV99371015; called by muse, mutect2, varscan2
- GPCPD1 | c.293C>G p.S98* | Nonsense Mutation (SNP) | VAF 61/214 reads (29%) | catalogued as COSV100980202; called by muse, mutect2, varscan2
- GPR148 | c.723G>T p.R241S | Missense Mutation (SNP) | VAF 46/196 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV99998614; called by muse, mutect2, varscan2
- GPT2 | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs931385054, COSV100412962; called by muse, mutect2, varscan2
- GREB1 | c.4703C>T p.A1568V | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.561); catalogued as COSV99303086; called by muse, mutect2, varscan2
- GRID1 | c.2712G>C p.E904D | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100024527; called by muse, mutect2, varscan2
- GRIN2B | c.4180G>T p.D1394Y | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101663075, COSV74206375; called by muse, mutect2
- GSN | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766916675, COSV100376312; called by muse, mutect2, varscan2
- GUCY1B1 | c.398T>C p.L133S | Missense Mutation (SNP) | VAF 70/180 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759205952, COSV100025631; called by muse, mutect2, varscan2
- GUCY2F | c.2484G>C p.L828F | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99485159; called by muse, mutect2, varscan2
- HCN1 | c.686C>G p.S229C | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100300714, COSV57538412; called by muse, mutect2, varscan2
- HDAC2 | c.364G>T p.A122S | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV100892655; called by muse, mutect2, varscan2
- HECW1 | c.385A>T p.K129* | Nonsense Mutation (SNP) | VAF 21/60 reads (35%) | catalogued as COSV101223842; called by muse, mutect2, varscan2
- HERC2 | c.10698G>T p.R3566S | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV99874540; called by muse, mutect2, varscan2
- HERC2 | c.6430G>T p.E2144* | Nonsense Mutation (SNP) | VAF 28/124 reads (23%) | catalogued as COSV99874544; called by muse, mutect2, varscan2
- HERPUD2 | c.226-1G>T p.X76_splice | Splice Site (SNP) | VAF 12/71 reads (17%) | catalogued as COSV100258001; called by muse, mutect2
- HGF | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99737319; called by muse, mutect2, varscan2
- HLX | c.1102A>G p.S368G | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV100854557; called by muse, mutect2, varscan2
- HNRNPM | c.2133G>T p.M711I | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.921); catalogued as COSV99725636; called by muse, mutect2, varscan2
- HRH2 | c.581C>A p.P194Q | Missense Mutation (SNP) | VAF 48/74 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99199698; called by muse, mutect2, varscan2
- HRNR | c.1349C>A p.S450Y | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100913583; called by muse, mutect2
- HTR3C | c.468G>A p.M156I | Missense Mutation (SNP) | VAF 49/361 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as COSV100570650; called by muse, varscan2
- IFT172 | c.3764G>A p.S1255N | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV99562665; called by muse, mutect2
- IGKV6D-41 | c.337A>G p.K113E | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1466073145; called by muse, mutect2, varscan2
- IKZF5 | c.466C>G p.H156D | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100924745; called by muse, mutect2, varscan2
- IL1F10 | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 118/456 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV100520188; called by muse, mutect2, varscan2
- IPO9 | c.1066G>C p.A356P | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.272); catalogued as COSV100843462; called by muse, mutect2
- ITPR2 | c.2650A>G p.R884G | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV101190034; called by muse, mutect2
- KBTBD6 | c.718T>C p.C240R | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.915); catalogued as COSV101068803; called by muse, mutect2, varscan2
- KCNQ3 | c.2392G>T p.E798* | Nonsense Mutation (SNP) | VAF 12/75 reads (16%) | catalogued as COSV101196197; called by muse, mutect2, varscan2
- KCNT2 | c.2657G>T p.R886M | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as COSV99654459; called by muse, mutect2, varscan2
- KDM4B | c.677-1G>C p.X226_splice | Splice Site (SNP) | VAF 74/311 reads (24%) | catalogued as COSV99346623; called by muse, mutect2, varscan2
- KIAA0319 | c.2722G>T p.V908F | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs764651788, COSV100985633; called by muse, varscan2
- KIAA1109 | c.4916+1G>C p.X1639_splice | Splice Site (SNP) | VAF 10/132 reads (8%) | catalogued as COSV99165074, COSV99165507; called by muse, mutect2
- KIAA1549L | c.4877G>A p.R1626K (on ENST00000321505; = p.R1923K on NM_012194.3) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV100381740; called by muse, mutect2, varscan2
- KIF1A | c.1890G>C p.Q630H | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100241354; called by muse, mutect2, varscan2
- KMT2B | c.4735C>T p.R1579C | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99719841; called by muse, mutect2, varscan2
- KPNA6 | c.1541A>C p.Q514P | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV101012534; called by muse, mutect2, varscan2
- LAMC3 | c.697G>T p.E233* | Nonsense Mutation (SNP) | VAF 41/181 reads (23%) | catalogued as COSV100736006; called by muse, mutect2, varscan2
- LATS1 | c.2785C>T p.Q929* | Nonsense Mutation (SNP) | VAF 24/50 reads (48%) | catalogued as COSV99486151; called by muse, mutect2, varscan2
- LCMT2 | c.1922_1923insG p.H641Qfs*5 | Frame Shift Ins (INS) | VAF 20/131 reads (15%) | catalogued as COSV99980111; called by mutect2, pindel, varscan2
- LCORL | c.269C>A p.S90* | Nonsense Mutation (SNP) | VAF 9/52 reads (17%) | catalogued as COSV100481605; called by muse, mutect2, varscan2
- LILRA4 | c.1031G>T p.C344F | Missense Mutation (SNP) | VAF 48/225 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99393184; called by muse, varscan2
- LIMCH1 | c.1099-2A>G p.X367_splice | Splice Site (SNP) | VAF 23/104 reads (22%) | catalogued as COSV100573926; called by muse, mutect2, varscan2
- LIPC | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.098); catalogued as COSV100134636, COSV54421550; called by muse, mutect2, varscan2
- LPIN1 | c.1103C>A p.S368Y | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV56769387, COSV99877707; called by muse, mutect2, varscan2
- LRP1 | c.5962G>A p.V1988I | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as COSV99676195; called by muse, mutect2, varscan2
- LRP1B | c.11171G>A p.R3724K | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV67187005; called by muse, mutect2, varscan2
- LRP1B | c.9160G>C p.E3054Q | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.255); catalogued as COSV101257808; called by mutect2, varscan2
- LRP4 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs1158489710, COSV101066671; called by muse, mutect2, varscan2
- LRRC6 | c.557A>C p.E186A | Missense Mutation (SNP) | VAF 40/224 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV99138090; called by muse, mutect2, varscan2
- LRRK2 | c.1657-1G>T p.X553_splice | Splice Site (SNP) | VAF 19/74 reads (26%) | catalogued as COSV100110513; called by muse, mutect2, varscan2
- LRRK2 | c.3882A>G p.I1294M | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.868); catalogued as rs1456225254, COSV100110516; called by muse, mutect2, varscan2
- LTBP1 | c.2473C>G p.L825V (on ENST00000404816 / NM_206943.4; = p.L499V on NM_000627.4) | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.105); catalogued as rs773221015, COSV100617331; called by muse, mutect2, varscan2
- MAP3K11 | c.1866G>C p.E622D | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.258); catalogued as COSV100442237; called by muse, mutect2, varscan2
- MAP3K4 | c.554A>G p.N185S | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.159); catalogued as rs980552320, COSV100815466; called by muse, mutect2
- MAPKBP1 | c.3215A>G p.H1072R (on ENST00000456763 / NM_001128608.2; = p.H1066R on NM_014994.3) | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99529680; called by muse, mutect2, varscan2
- MARS1 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 73/268 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as COSV100007444; called by muse, mutect2, varscan2
- MASP1 | c.1266T>A p.N422K | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99397282; called by muse, mutect2
- MC2R | c.814G>C p.D272H | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100563054; called by muse, mutect2, varscan2
- MCF2 | c.186C>A p.S62R | Missense Mutation (SNP) | VAF 73/114 reads (64%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.737); catalogued as COSV100644841, COSV58481114; called by muse, mutect2, varscan2
- MED24 | c.2599G>T p.D867Y | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); catalogued as COSV99842463; called by muse, mutect2, varscan2
- MEFV | c.9G>C p.K3N | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as COSV99561005; called by muse, mutect2, varscan2
- MICAL3 | c.2069A>G p.E690G | Missense Mutation (SNP) | VAF 55/229 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as COSV99261919; called by muse, mutect2, varscan2
- MINAR1 | c.2083C>T p.R695W | Missense Mutation (SNP) | VAF 72/247 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as rs756124862, COSV59586512; called by muse, mutect2, varscan2
- MLLT1 | c.508T>G p.S170A | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as COSV99398068; called by muse, mutect2, varscan2
- MLLT3 | c.383C>T p.T128I | Missense Mutation (SNP) | VAF 55/282 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100581022; called by muse, mutect2, varscan2
- MPDZ | c.2758G>C p.D920H | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.352); catalogued as COSV100056989; called by muse, mutect2
- MS4A1 | c.17A>T p.N6I | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100619347; called by muse, mutect2, varscan2
- MUC16 | c.42891C>A p.Y14297* | Nonsense Mutation (SNP) | VAF 20/71 reads (28%) | catalogued as COSV101109931; called by muse, mutect2, varscan2
- MUC16 | c.14185A>T p.K4729* | Nonsense Mutation (SNP) | VAF 13/216 reads (6%) | catalogued as COSV101200195; called by muse, mutect2
- MX1 | c.646G>T p.V216L | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99912707; called by muse, mutect2, varscan2
- MYH15 | c.1274G>C p.R425T | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV99843478; called by muse, mutect2, varscan2
- MYH2 | c.4759G>T p.E1587* | Nonsense Mutation (SNP) | VAF 51/103 reads (50%) | catalogued as COSV55448636, COSV99820366; called by muse, mutect2, varscan2
- MYO3B | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.221); catalogued as COSV100510549; called by muse, mutect2, varscan2
- MYO6 | c.1489C>G p.Q497E | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (1); PolyPhen possibly damaging (0.744); catalogued as rs767084275, COSV100889370; called by muse, mutect2, varscan2
- MYO9B | c.326T>A p.L109Q | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101261631; called by muse, mutect2
- NAGLU | c.1986G>C p.Q662H | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99864195; called by muse, mutect2, varscan2
- NCOR1 | c.4592C>T p.A1531V | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs151311067; called by muse, mutect2, varscan2
- NELL1 | c.1397A>T p.Y466F | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.534); catalogued as COSV100122097; called by muse, mutect2, varscan2
- NEURL1 | c.457T>A p.W153R | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100872786; called by muse, mutect2, varscan2
- NEXMIF | c.3011G>C p.S1004T | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV99281039; called by muse, mutect2, varscan2
- NLRP2 | c.1303A>C p.S435R | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.243); catalogued as rs1199328756, COSV99672357; called by muse, mutect2, varscan2
- NLRP8 | c.1004G>C p.R335T | Missense Mutation (SNP) | VAF 47/231 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99405417; called by muse, mutect2, varscan2
- NMRK2 | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as COSV51454954, COSV99396383; called by muse, mutect2, varscan2
- NOX1 | c.340A>C p.I114L | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.262); catalogued as COSV99471596; called by muse, mutect2, varscan2
- NPL | c.67G>A p.G23R | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV99277627; called by muse, mutect2, varscan2
- NRAP | c.4439A>C p.Y1480S (on ENST00000359988 / NM_001322945.2; = p.Y1445S on NM_006175.4) | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100748469; called by muse, mutect2, varscan2
- NRXN1 | c.2612G>A p.S871N | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100455523; called by muse, mutect2, varscan2
- NUTM1 | c.431C>A p.P144H | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100412370; called by muse, mutect2, varscan2
- NUTM1 | c.2099G>C p.S700T | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as COSV100149043; called by muse, mutect2, varscan2
- OOSP2 | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 22/96 reads (23%) | catalogued as COSV53928347, COSV99613480; called by muse, mutect2, varscan2
- OPN4 | c.56G>A p.C19Y | Missense Mutation (SNP) | VAF 6/127 reads (5%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.017); catalogued as COSV54116975; called by muse, mutect2
- OR2A5 | c.692G>C p.G231A | Missense Mutation (SNP) | VAF 10/274 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as COSV101278804; called by muse, mutect2
- OR2T10 | c.566G>C p.C189S | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100393732; called by muse, mutect2, varscan2
- OR2T6 | c.731A>T p.H244L | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1421617826, COSV100861577; called by muse, mutect2, varscan2
- OR4M1 | c.716T>C p.M239T | Missense Mutation (SNP) | VAF 52/223 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs555006446, COSV100271277; called by muse, mutect2, varscan2
- OR4S2 | c.922G>C p.A308P | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.143); catalogued as COSV100412694, COSV56747218; called by muse, mutect2, varscan2
- OR51A2 | c.376C>G p.L126V | Missense Mutation (SNP) | VAF 86/188 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.1); catalogued as rs1242359100, COSV100985066; called by muse, mutect2, varscan2
- OR5A1 | c.421C>A p.Q141K | Missense Mutation (SNP) | VAF 104/440 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.055); catalogued as COSV100118389; called by muse, mutect2, varscan2
- OR5H2 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV100788745; called by muse, mutect2, varscan2
- OR5H6 | c.38G>A p.C13Y | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV101051784; called by muse, mutect2, varscan2
- OR7D4 | c.380G>T p.C127F | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100432761; called by muse, mutect2, varscan2
- OR8K1 | c.337T>C p.F113L | Missense Mutation (SNP) | VAF 65/262 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.101); catalogued as COSV99687365; called by muse, mutect2, varscan2
- OSGEP | c.946A>T p.S316C | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.325); catalogued as COSV99248033; called by muse, mutect2, varscan2
- P3H1 | c.1002C>G p.D334E | Missense Mutation (SNP) | VAF 31/285 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV52535981, COSV99355307; called by muse, mutect2, varscan2
- PAPLN | c.920G>T p.S307I (on ENST00000554301; = p.S280I on NM_173462.4) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.491); catalogued as COSV99389827; called by muse, mutect2, varscan2
- PAPPA2 | c.86C>A p.T29K | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV100866839; called by muse, mutect2
- PAPPA2 | c.4845C>G p.D1615E | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as COSV100868289; called by muse, mutect2, varscan2
- PCDHA1 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.786); catalogued as COSV65373470; called by muse, mutect2, varscan2
- PCDHA6 | c.1268T>A p.L423* | Nonsense Mutation (SNP) | VAF 115/290 reads (40%) | catalogued as COSV101136068; called by muse, mutect2, varscan2
- PCDHA8 | c.1868G>A p.R623H | Missense Mutation (SNP) | VAF 88/213 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.12); catalogued as rs200720426, COSV65323235; called by muse, mutect2, varscan2
- PCDHA8 | c.1985C>T p.T662M | Missense Mutation (SNP) | VAF 96/220 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.946); catalogued as rs1393236321, COSV65324971; called by muse, mutect2, varscan2
- PCDHB7 | c.1897C>A p.R633S | Missense Mutation (SNP) | VAF 70/374 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as rs781789532, COSV50760971, COSV99177072; called by muse, mutect2, varscan2
- PCGF1 | c.712C>G p.L238V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.96); PolyPhen benign (0.048); catalogued as COSV99283353; called by muse, mutect2, varscan2
- PCGF5 | c.592G>T p.G198C | Missense Mutation (SNP) | VAF 39/192 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100277692; called by muse, mutect2, varscan2
- PDPR | c.1897G>C p.D633H | Missense Mutation (SNP) | VAF 67/226 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV99848452; called by muse, mutect2, varscan2
- PDZD8 | c.663G>T p.K221N | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV100559542; called by muse, mutect2
- PEG3 | c.3552C>G p.I1184M | Missense Mutation (SNP) | VAF 10/271 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.244); catalogued as COSV99689314; called by muse, mutect2
- PGAM4 | c.121G>A p.G41S | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.218); catalogued as rs376675574, COSV100431030; called by muse, mutect2
- PI4KA | c.5392G>T p.A1798S | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99746759; called by muse, mutect2, varscan2
- PIAS1 | c.1025T>A p.L342Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99986847; called by muse, mutect2, varscan2
- PIKFYVE | c.5485G>T p.E1829* | Nonsense Mutation (SNP) | VAF 64/203 reads (32%) | catalogued as COSV100010909; called by muse, mutect2, varscan2
- PKHD1L1 | c.9050C>G p.S3017* | Nonsense Mutation (SNP) | VAF 23/57 reads (40%) | catalogued as COSV101006311; called by muse, mutect2, varscan2
- PKN1 | c.838G>T p.A280S | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.33); catalogued as COSV54399744, COSV99661375; called by muse, mutect2
- PLEC | c.4991C>G p.A1664G (on ENST00000322810 / NM_201380.4; = p.A1554G on NM_000445.5) | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs782569624, COSV100515365; called by muse, mutect2, varscan2
- PLEKHA4 | c.1396G>C p.E466Q | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.986); catalogued as COSV54364619, COSV99612697; called by muse, mutect2, varscan2
- PLEKHM1 | c.393G>T p.M131I | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as COSV101378772; called by muse, mutect2
- PLLP | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs754274845, COSV99536099; called by muse, mutect2, varscan2
- PLPP2 | c.226C>G p.L76V | Missense Mutation (SNP) | VAF 99/430 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.086); catalogued as COSV99514700; called by muse, mutect2, varscan2
- PLTP | c.1305G>C p.Q435H | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.121); catalogued as COSV99509933; called by muse, mutect2, varscan2
- PM20D2 | c.1108A>T p.I370F | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99248387; called by muse, mutect2, varscan2
- PMVK | c.182G>A p.R61K | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as COSV100870517; called by muse, mutect2
- PNLIPRP3 | c.560T>C p.I187T | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100982514; called by muse, mutect2
- POLQ | c.2414A>T p.Q805L | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV99952393; called by muse, mutect2, varscan2
- POPDC2 | c.748G>C p.D250H | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as COSV99951054; called by muse, mutect2, varscan2
- POU2F1 | c.1172G>T p.R391L (on ENST00000541643 / NM_001365848.1; = p.R414L on NM_002697.4) | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV54821456, COSV99611322; called by muse, mutect2, varscan2
- POU4F2 | c.750C>G p.D250E | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.403); catalogued as COSV99850466, COSV99850611; called by muse, mutect2, varscan2
- PPFIA3 | c.1113G>C p.L371F | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as COSV100494997; called by muse, mutect2
- PPP1CB | c.918T>A p.Y306* | Nonsense Mutation (SNP) | VAF 10/146 reads (7%) | catalogued as COSV99941872; called by muse, mutect2
- PPP1CC | c.229G>T p.E77* | Nonsense Mutation (SNP) | VAF 6/98 reads (6%) | catalogued as COSV100534889, COSV58584450; called by muse, mutect2
- PRDM9 | c.1033C>G p.R345G | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV57009868, COSV57014196; called by muse, mutect2, varscan2
- PRUNE2 | c.4399G>T p.E1467* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as COSV100944732, COSV65045963; called by muse, mutect2, varscan2
- PSMB6 | c.608C>A p.S203Y | Missense Mutation (SNP) | VAF 27/213 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99566993; called by muse, mutect2, varscan2
- PSME4 | c.2747A>G p.K916R | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.395); catalogued as COSV101122442, COSV101122538; called by muse, mutect2, varscan2
- PTCH2 | c.1202G>T p.G401V | Missense Mutation (SNP) | VAF 15/169 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100942143; called by muse, mutect2
- PTCHD4 | c.2135G>A p.C712Y | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as rs1445287862, COSV100261095; called by muse, mutect2, varscan2
- PTPN4 | c.1168T>C p.S390P | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.135); catalogued as rs781516454, COSV99750446; called by muse, mutect2, varscan2
- RAB19 | c.4C>G p.H2D | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV52046319, COSV99325127; called by muse, mutect2, varscan2
- RAI1 | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs907728820, COSV99884285; called by muse, mutect2
- RAP1GAP | c.-112G>C | Splice Region (SNP) | VAF 11/82 reads (13%) | catalogued as COSV99265411; called by muse, mutect2, varscan2
- RBP1 | c.334G>C p.E112Q (on ENST00000619087 / NM_001365940.2; = p.E174Q on NM_002899.5) | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.347); catalogued as COSV99218972; called by muse, mutect2
- REG3G | c.145del p.S49Pfs*44 | Frame Shift Del (DEL) | VAF 14/109 reads (13%) | catalogued as rs868833238, COSV99042303; called by mutect2, varscan2
- REG3G | c.150del p.C51Afs*42 | Frame Shift Del (DEL) | VAF 12/119 reads (10%) | catalogued as COSV55450544, COSV55450874; called by mutect2*, pindel, varscan2*
- RELCH | c.134G>A p.S45N | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.014); catalogued as COSV99902247; called by muse, mutect2, varscan2
- RFX1 | c.269C>A p.A90E | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV99586203; called by muse, mutect2
- RNF144A | c.532G>T p.D178Y | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV100305710, COSV100305790; called by muse, mutect2, varscan2
- RNF19A | c.450T>G p.C150W | Missense Mutation (SNP) | VAF 61/133 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100347804; called by muse, mutect2, varscan2
- RPS6KA1 | c.1523C>G p.S508* | Nonsense Mutation (SNP) | VAF 45/131 reads (34%) | catalogued as COSV100943157; called by muse, mutect2, varscan2
- RTN1 | c.1910G>C p.S637T | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99955917; called by muse, mutect2, varscan2
- RYR1 | c.146A>G p.E49G | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100616023; called by muse, mutect2, varscan2
- SAP130 | c.1504C>T p.H502Y | Missense Mutation (SNP) | VAF 53/170 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.439); catalogued as COSV99384832; called by muse, mutect2, varscan2
- SART3 | c.2540A>G p.D847G (on ENST00000228284; = p.D829G on NM_014706.4) | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.111); catalogued as COSV99934143; called by muse, mutect2, varscan2
- SART3 | c.1903A>G p.I635V (on ENST00000228284; = p.I617V on NM_014706.4) | Missense Mutation (SNP) | VAF 63/191 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99934144; called by muse, mutect2, varscan2
- SCN5A | c.1463A>G p.E488G | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.134); catalogued as COSV100348922; called by muse, mutect2, varscan2
- SCN7A | c.4336A>C p.S1446R | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as COSV101313260; called by muse, mutect2, varscan2
- SCN8A | c.5866G>C p.E1956Q | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); catalogued as COSV100633952; called by muse, mutect2, varscan2
- SEC22A | c.299T>C p.M100T | Missense Mutation (SNP) | VAF 50/202 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59371185; called by muse, mutect2, varscan2
- SELE | c.477T>A p.N159K | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV100324852; called by muse, mutect2
- SELENON | c.573G>T p.W191C | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100823522; called by muse, mutect2, varscan2
- SEPHS2 | c.1087C>A p.L363I | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.445); catalogued as COSV101529332; called by muse, varscan2
- SEZ6L2 | c.255G>T p.Q85H | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.648); catalogued as COSV100435545; called by muse, mutect2, varscan2
- SFRP2 | c.498G>T p.E166D | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as COSV99923356; called by muse, mutect2, varscan2
- SFXN5 | c.813G>A p.M271I | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV55586120; called by muse, mutect2
- SH3GLB1 | c.863G>C p.S288T | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV100990791; called by muse, mutect2, varscan2
- SHOX2 | c.20T>C p.F7S | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as rs1411339492, COSV99906375; called by muse, mutect2
- SHROOM1 | c.1809A>T p.P603= | Splice Region (SNP) | VAF 54/155 reads (35%) | catalogued as COSV100167139; called by muse, mutect2, varscan2
- SIGLEC6 | c.1321G>T p.V441F | Missense Mutation (SNP) | VAF 17/274 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.403); catalogued as rs770259451, COSV100585476, COSV58431763; called by muse, mutect2
- SIX1 | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99903387; called by muse, mutect2, varscan2
- SLC25A53 | c.562G>T p.G188W | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100656026; called by muse, mutect2, varscan2
- SLC36A1 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.013); catalogued as COSV99695608; called by muse, mutect2, varscan2
- SLC39A12 | c.1573G>T p.G525C (on ENST00000377369 / NM_001145195.2; = p.G488C on NM_152725.3) | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.614); catalogued as COSV101070075; called by muse, mutect2, varscan2
- SLC4A4 | c.1795G>T p.D599Y (on ENST00000264485 / NM_001098484.3; = p.D555Y on NM_003759.4) | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99140458; called by muse, mutect2, varscan2
- SLC5A12 | c.73G>T p.G25W | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54821043, COSV99745069; called by muse, mutect2, varscan2
- SLC6A16 | c.1133C>A p.S378Y | Missense Mutation (SNP) | VAF 13/204 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV100242819; called by muse, mutect2
- SLC9C2 | c.200T>G p.I67R | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV100876802; called by muse, mutect2, varscan2
- SMG7 | c.1452G>C p.L484F | Missense Mutation (SNP) | VAF 11/203 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as COSV100750376; called by muse, mutect2
- SMG8 | c.94G>C p.G32R | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated, low confidence (0.39); PolyPhen possibly damaging (0.455); catalogued as COSV99958891; called by muse, mutect2, varscan2
- SMYD4 | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 67/134 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.124); catalogued as COSV100563082; called by muse, mutect2, varscan2
- SORCS2 | c.3029G>A p.G1010E | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs760207977, COSV61173129; called by muse, varscan2
- SPATC1 | c.592C>G p.P198A | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.443); catalogued as COSV101085057; called by muse, mutect2
- SPEN | c.1221A>C p.E407D | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.279); catalogued as rs1463367834, COSV101005287; called by muse, mutect2, varscan2
- SPTY2D1 | c.1663C>G p.Q555E | Missense Mutation (SNP) | VAF 9/182 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as COSV100311722; called by muse, mutect2
- SPZ1 | c.631G>T p.V211L | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.043); catalogued as rs1363540260, COSV99698204; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.497C>A p.T166N | Missense Mutation (SNP) | VAF 30/121 reads (25%) | PolyPhen possibly damaging (0.906); catalogued as COSV100602811; called by muse, mutect2, varscan2
- STAT6 | c.1072G>C p.A358P | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100273374; called by muse, mutect2, varscan2
- SUN1 | c.405G>T p.L135F (on ENST00000405266 / NM_001367651.1; = p.L85F on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100568703, COSV61777425; called by muse, varscan2
- SURF2 | c.355C>A p.Q119K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.767); catalogued as rs1276514594, COSV100914348; called by muse, varscan2
- SYNC | c.1447T>C p.*483Qext*16 | Nonstop Mutation (SNP) | VAF 5/83 reads (6%) | catalogued as COSV100995335; called by muse, mutect2
- SYNE1 | c.8488G>T p.E2830* (on ENST00000367255 / NM_182961.4; = p.E2837* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 50/93 reads (54%) | catalogued as COSV54937282, COSV99567787; called by muse, mutect2, varscan2
- SYNE1 | c.8488-1G>T p.X2830_splice (on ENST00000367255 / NM_182961.4; = p.X2837_splice on NM_033071.3) | Splice Site (SNP) | VAF 50/94 reads (53%) | catalogued as COSV99567792; called by muse, mutect2, varscan2
- SYNE1 | c.8189C>G p.S2730C (on ENST00000367255 / NM_182961.4; = p.S2737C on NM_033071.3) | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.376); catalogued as COSV99567800; called by muse, mutect2
- SZT2 | c.5152C>G p.P1718A (on ENST00000634258 / NM_001365999.1; = p.P1661A on NM_015284.4) | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV100987403; called by muse, mutect2, varscan2
- TARBP1 | c.2716C>G p.L906V | Missense Mutation (SNP) | VAF 50/214 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs1034306854, COSV99241766; called by muse, mutect2, varscan2
- TAX1BP1 | c.233G>T p.G78V | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99604534; called by muse, mutect2
- TBC1D2B | c.2163C>G p.N721K | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100317385; called by muse, mutect2
- TDRD6 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs201878062, COSV100287782; called by muse, mutect2, varscan2
- TENM2 | c.4365C>A p.H1455Q (on ENST00000518659 / NM_001122679.2; = p.H1216Q on NM_001080428.3) | Missense Mutation (SNP) | VAF 11/339 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV101318917; called by muse, mutect2
- TENM3 | c.6006G>T p.R2002S | Missense Mutation (SNP) | VAF 115/413 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); catalogued as COSV101305186; called by muse, mutect2, varscan2
- TFAP2A | c.212C>G p.S71W (on ENST00000482890; = p.S63W on NM_001032280.3) | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); catalogued as COSV100116998, COSV60232849; called by muse, mutect2, varscan2
- TFAP2E | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100951477; called by muse, mutect2
- THAP2 | c.224C>A p.A75D | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100350503; called by muse, mutect2, varscan2
- THSD7B | c.4369G>A p.V1457I (on ENST00000272643; = p.V1455I on NM_001316349.2) | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs147732921, COSV99752663; called by muse, mutect2, varscan2
- TIAM1 | c.1307A>G p.K436R | Missense Mutation (SNP) | VAF 70/160 reads (44%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); catalogued as COSV99735883; called by muse, mutect2, varscan2
- TJP3 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.86); catalogued as rs367879011; called by muse, mutect2, varscan2
- TLN1 | c.2335A>C p.N779H | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV100147849; called by muse, mutect2, varscan2
- TLN2 | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100169268, COSV60891066; called by muse, mutect2
- TLR7 | c.2233G>T p.D745Y | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV101027931; called by muse, mutect2, varscan2
- TM4SF5 | c.187C>A p.P63T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV99564476, COSV99564724; called by mutect2, varscan2
- TMEM108 | c.1340T>C p.I447T | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV100419023, COSV100419281; called by muse, mutect2, varscan2
- TMEM131L | c.2200C>A p.P734T | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99547638; called by muse, mutect2, varscan2
- TMEM38A | c.134A>G p.E45G | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.871); catalogued as COSV99495302; called by muse, mutect2, varscan2
- TMEM87B | c.730G>C p.D244H | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99314426; called by muse, mutect2, varscan2
- TMPRSS15 | c.2636T>A p.M879K | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV99518226; called by muse, mutect2, varscan2
- TNNI2 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99425502; called by muse, mutect2, varscan2
- TOGARAM1 | c.3619C>G p.R1207G | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV100818087; called by muse, mutect2
- TRA2B | c.362G>C p.G121A | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV99373286; called by muse, mutect2, varscan2
- TRAF3IP2 | c.1433A>G p.D478G | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100389771; called by muse, mutect2, varscan2
- TRDN | c.176C>A p.T59K | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as CM124195, COSV100522049, COSV100522303; called by muse, mutect2, varscan2
- TRIL | c.548A>G p.Y183C | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100538847; called by muse, mutect2, varscan2
- TRIP13 | c.1069G>C p.E357Q | Missense Mutation (SNP) | VAF 120/431 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.115); catalogued as COSV99386427; called by muse, mutect2, varscan2
- TRPC4AP | c.814C>G p.Q272E | Missense Mutation (SNP) | VAF 55/194 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV52680647, COSV99328505; called by muse, mutect2, varscan2
- TRPM1 | c.2564G>C p.G855A | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV99856094; called by muse, mutect2, varscan2
- TTC17 | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 62/267 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); catalogued as COSV50013514, COSV50025524; called by muse, mutect2, varscan2
- TTC4 | c.298A>C p.I100L | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV100988440; called by muse, mutect2, varscan2
- TTK | c.94C>G p.L32V | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.051); catalogued as COSV100036372; called by muse, mutect2
- TTN | c.66343G>C p.G22115R (on ENST00000591111; = p.G14691R on NM_003319.4) | Missense Mutation (SNP) | VAF 24/43 reads (56%) | PolyPhen probably damaging (1); catalogued as COSV100617704; called by muse, mutect2, varscan2
- TTN | c.55778C>A p.P18593Q (on ENST00000591111; = p.P11169Q on NM_003319.4) | Missense Mutation (SNP) | VAF 164/317 reads (52%) | PolyPhen possibly damaging (0.9); catalogued as COSV100617707; called by muse, mutect2, varscan2
- TTN | c.55777C>A p.P18593T (on ENST00000591111; = p.P11169T on NM_003319.4) | Missense Mutation (SNP) | VAF 162/312 reads (52%) | PolyPhen benign (0.084); catalogued as COSV100617708; called by muse, mutect2, varscan2
- TTN | c.33107T>A p.F11036Y (on ENST00000591111; = p.F10109Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/159 reads (54%) | PolyPhen benign (0); catalogued as COSV100617709; called by muse, mutect2, varscan2
- TXN2 | c.99G>T p.Q33H | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99340457; called by muse, mutect2, varscan2
- UBR4 | c.10126G>C p.E3376Q | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.954); catalogued as rs1465866709, COSV100921079; called by muse, mutect2, varscan2
- ULK3 | c.487C>A p.H163N | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as rs1200408817, COSV99173969; called by muse, mutect2, varscan2
- UMODL1 | c.2449G>C p.D817H (on ENST00000408910 / NM_001004416.2; = p.D945H on NM_173568.3) | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.764); catalogued as COSV101252606; called by muse, mutect2
- UNC5CL | c.849C>G p.N283K | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV99770836; called by muse, mutect2
- USP19 | c.1113C>A p.C371* | Nonsense Mutation (SNP) | VAF 14/48 reads (29%) | catalogued as COSV100026249; called by muse, mutect2, varscan2
- USP9X | c.7403C>A p.A2468E | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV100199456; called by muse, mutect2, varscan2
- VPS13C | c.8169G>T p.W2723C (on ENST00000644861 / NM_020821.3; = p.W2680C on NM_017684.5) | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99828819; called by muse, mutect2
- VPS39 | c.2405T>C p.I802T (on ENST00000348544 / NM_001301138.2; = p.I791T on NM_015289.5) | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV100529300; called by muse, mutect2, varscan2
- WDR64 | c.2815A>T p.T939S | Missense Mutation (SNP) | VAF 9/153 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.293); catalogued as COSV100843813; called by muse, mutect2
- WDR72 | c.1130T>C p.L377P | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100854610; called by muse, mutect2
- WNK4 | c.1640C>T p.A547V | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs757547531, COSV99890569; called by muse, mutect2, varscan2
- WSCD2 | c.937G>T p.G313W | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.228); catalogued as COSV99774753; called by muse, mutect2, varscan2
- XPO6 | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 9/49 reads (18%) | catalogued as COSV100485097; called by muse, varscan2
- ZDHHC11 | c.158C>G p.S53C | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as COSV99363011; called by muse, mutect2
- ZFAT | c.1936G>T p.E646* | Nonsense Mutation (SNP) | VAF 31/112 reads (28%) | catalogued as COSV100914710, COSV64734521; called by muse, mutect2, varscan2
- ZFP69 | c.1547T>A p.I516K | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.302); catalogued as COSV101018275; called by muse, mutect2, varscan2
- ZIC1 | c.663C>G p.I221M | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99292052; called by muse, mutect2, varscan2
- ZMYND15 | c.1271C>A p.T424K | Missense Mutation (SNP) | VAF 82/188 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.091); catalogued as rs558547388, COSV99351435, COSV99351667; called by muse, mutect2, varscan2
- ZNF257 | c.1451A>G p.E484G | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.194); catalogued as COSV101448113, COSV71311195; called by muse, mutect2, varscan2
- ZNF260 | c.555C>G p.I185M | Missense Mutation (SNP) | VAF 61/232 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as COSV101591062; called by muse, mutect2, varscan2
- ZNF30 | c.1005G>C p.Q335H | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.199); catalogued as COSV100340606; called by muse, mutect2
- ZNF385B | c.1168C>G p.R390G | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100416089, COSV100416354; called by muse, mutect2
- ZNF394 | c.895C>T p.Q299* | Nonsense Mutation (SNP) | VAF 40/175 reads (23%) | catalogued as rs1176955825, COSV100529909; called by muse, mutect2, varscan2
- ZNF407 | c.3856G>T p.A1286S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99995949; called by muse, mutect2
- ZNF507 | c.1050G>T p.Q350H | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100321896; called by muse, mutect2
- ZNF536 | c.1726C>G p.Q576E | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.467); catalogued as COSV100835349; called by muse, mutect2, varscan2
- ZNF560 | c.2368C>A p.H790N | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV100038703; called by muse, mutect2, varscan2
- ZNF578 | c.1440G>T p.E480D | Missense Mutation (SNP) | VAF 72/135 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV101405063; called by muse, mutect2, varscan2
- ZNF624 | c.898A>G p.K300E | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV100257294; called by muse, mutect2, varscan2
- ZNF669 | c.464A>C p.Q155P | Missense Mutation (SNP) | VAF 47/196 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.161); catalogued as COSV100594284; called by muse, mutect2, varscan2
- ZNF83 | c.1040G>C p.C347S | Missense Mutation (SNP) | VAF 15/246 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99991427; called by muse, mutect2
- ZNF836 | c.916G>C p.E306Q | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV100441014; called by muse, mutect2, varscan2
- ZSCAN22 | c.654G>C p.Q218H | Missense Mutation (SNP) | VAF 19/417 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.431); catalogued as COSV100308391; called by muse, mutect2
- ZSCAN5B | c.1124G>T p.R375M | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100627993; called by muse, mutect2, varscan2
- ZYX | c.1525G>C p.E509Q | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); catalogued as COSV99314151; called by muse, mutect2
- ABRAXAS1 | c.650_654del p.E217Vfs*19 | Frame Shift Del (DEL) | VAF 14/57 reads (25%) | called by pindel, varscan2
- ACHE | c.789del p.N264Mfs*38 | Frame Shift Del (DEL) | VAF 14/57 reads (25%) | called by mutect2, pindel, varscan2
- AKAP11 | c.2020_2026del p.P674Vfs*10 | Frame Shift Del (DEL) | VAF 8/74 reads (11%) | called by mutect2, pindel
- ALDH18A1 | c.1392_1411del p.L464Ffs*11 | Frame Shift Del (DEL) | VAF 16/108 reads (15%) | called by mutect2, pindel
- ARHGAP36 | c.248_253+20del p.X83_splice | Splice Site (DEL) | VAF 24/100 reads (24%) | called by mutect2, pindel
- CPN2 | c.372del p.K125Sfs*44 | Frame Shift Del (DEL) | VAF 28/154 reads (18%) | called by mutect2, pindel, varscan2
- FOXP1 | c.892del p.H298Ifs*27 | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | called by mutect2, pindel, varscan2
- GDF10 | c.405C>G p.F135L | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- GRIA2 | c.1641del p.W547* | Frame Shift Del (DEL) | VAF 60/245 reads (24%) | called by mutect2, pindel, varscan2
- IGBP1P2 | c.80A>T p.E27V | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- IGKV1D-8 | c.157A>T p.S53C | Missense Mutation (SNP) | VAF 50/197 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- ISLR | c.646C>T p.L216F | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.503); called by muse, varscan2
- LRRC4B | c.1406del p.G469Afs*22 | Frame Shift Del (DEL) | VAF 31/77 reads (40%) | called by mutect2, pindel, varscan2
- OR1C1 | c.450dup p.V151Cfs*30 | Frame Shift Ins (INS) | VAF 17/79 reads (22%) | called by mutect2, pindel, varscan2
- OR8G2P | c.303_314del p.Y102_L105del | In Frame Del (DEL) | VAF 36/166 reads (22%) | called by mutect2, pindel, varscan2
- PBRM1 | c.4082del p.P1361Hfs*23 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | called by mutect2, pindel, varscan2
- PDHA1 | c.783_809del p.V262_A270del | In Frame Del (DEL) | VAF 5/43 reads (12%) | called by mutect2, pindel
- PROKR2 | c.351_356dup p.Q118_L119dup | In Frame Ins (INS) | VAF 25/88 reads (28%) | called by mutect2, pindel, varscan2
- PZP | c.4116del p.I1373Sfs*13 | Frame Shift Del (DEL) | VAF 42/108 reads (39%) | called by mutect2, pindel*, varscan2
- SLC22A16 | c.949del p.A317Qfs*48 | Frame Shift Del (DEL) | VAF 24/88 reads (27%) | called by mutect2, pindel, varscan2
- SOS2 | c.3774_3787del p.P1259* | Frame Shift Del (DEL) | VAF 9/95 reads (9%) | called by mutect2, pindel
- USP47 | c.2716del p.E906Kfs*43 (on ENST00000399455 / NM_001372095.1; = p.E818Kfs*43 on NM_017944.4 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 21/73 reads (29%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.313_314del p.P105Afs*13 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | called by pindel, varscan2
- ADAM7 | c.936C>G p.P312= | Silent (SNP) | VAF 9/88 reads (10%) | called by muse, mutect2, varscan2
- ADNP | c.1512C>T p.L504= | Silent (SNP) | VAF 30/262 reads (11%) | catalogued as COSV100823771; called by muse, mutect2, varscan2
- AGO4 | c.45A>T p.P15= | Silent (SNP) | VAF 48/165 reads (29%) | catalogued as COSV100942987; called by muse, mutect2, varscan2
- AHSG | c.339C>T p.D113= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV99890110; called by muse, mutect2, varscan2
- AKR1B15 | c.369G>A p.K123= | Silent (SNP) | VAF 13/124 reads (10%) | catalogued as COSV101423376; called by muse, mutect2, varscan2
- ALPK1 | c.1380A>G p.S460= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as COSV99454333; called by muse, mutect2, varscan2
- AOC1 | c.48G>A p.T16= | Silent (SNP) | VAF 32/83 reads (39%) | catalogued as rs374700351, COSV100710999; called by muse, mutect2, varscan2
- AP5B1 | c.1479G>T p.L493= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV100376076; called by muse, mutect2, varscan2
- APBB1IP | c.699T>C p.F233= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV100770902; called by muse, mutect2
- ARMC12 | c.270G>A p.L90= (on ENST00000373866 / NM_001286574.2; = p.L117= on NM_145028.5) | Silent (SNP) | VAF 109/203 reads (54%) | catalogued as COSV99849484; called by muse, mutect2, varscan2
- ASPM | c.5859G>T p.V1953= | Silent (SNP) | VAF 35/163 reads (21%) | catalogued as COSV99660572; called by muse, mutect2, varscan2
- AVPI1 | c.237C>A p.P79= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV101033318; called by muse, mutect2, varscan2
- C2orf78 | c.567A>T p.T189= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as COSV101280989; called by muse, mutect2, varscan2
- CACNG8 | c.90C>T p.A30= | Silent (SNP) | VAF 41/68 reads (60%) | catalogued as COSV99555040; called by muse, mutect2, varscan2
- CADPS | c.2745A>G p.S915= | Silent (SNP) | VAF 170/458 reads (37%) | catalogued as COSV99338879; called by muse, varscan2
- CCN4 | c.168G>T p.P56= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as COSV99136939, COSV99137149; called by muse, mutect2, varscan2
- CD84 | c.645C>T p.I215= | Silent (SNP) | VAF 24/111 reads (22%) | catalogued as rs368931230, COSV60869553; called by muse, mutect2, varscan2
- CDC42BPG | c.3274C>T p.L1092= | Silent (SNP) | VAF 8/118 reads (7%) | catalogued as COSV100712103; called by muse, mutect2
- CDH16 | c.1251G>A p.V417= | Silent (SNP) | VAF 5/92 reads (5%) | catalogued as COSV100233930; called by muse, mutect2
- CELSR1 | c.8526C>G p.A2842= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV99418673; called by muse, mutect2, varscan2
- CEP72 | c.150G>A p.L50= | Silent (SNP) | VAF 16/206 reads (8%) | catalogued as COSV99374926; called by muse, mutect2
- CKM | c.507C>T p.F169= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs372948338, COSV55535494; called by muse, mutect2, varscan2
- CPXM2 | c.1683C>T p.L561= | Silent (SNP) | VAF 21/80 reads (26%) | catalogued as COSV99582510; called by muse, mutect2, varscan2
- CRB1 | c.3093T>C p.D1031= | Silent (SNP) | VAF 37/113 reads (33%) | catalogued as rs1169046915, COSV100957929; called by muse, mutect2, varscan2
- CRMP1 | c.828A>G p.G276= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV100271986; called by muse, mutect2, varscan2
- CSMD3 | c.48C>A p.P16= | Silent (SNP) | VAF 63/177 reads (36%) | catalogued as COSV99837018; called by muse, mutect2, varscan2
- CTRB2 | c.702C>A p.G234= | Silent (SNP) | VAF 36/113 reads (32%) | catalogued as COSV100274731; called by muse, mutect2, varscan2
- CUL2 | c.1425G>T p.R475= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV101039178; called by muse, mutect2
- CYP4F8 | c.360G>A p.K120= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV100358142; called by muse, mutect2, varscan2
- DAAM2 | c.2736C>T p.V912= (on ENST00000274867 / NM_001201427.2; = p.V911= on NM_015345.3) | Silent (SNP) | VAF 11/17 reads (65%) | catalogued as COSV99225964; called by muse, mutect2, varscan2
- DCST2 | c.1248C>G p.L416= | Silent (SNP) | VAF 15/211 reads (7%) | catalogued as COSV55050308, COSV99792011; called by muse, mutect2
- DESI2 | c.27C>G p.L9= | Silent (SNP) | VAF 20/184 reads (11%) | catalogued as COSV99798243; called by muse, mutect2, varscan2
- DGKQ | c.945C>G p.R315= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as COSV99892848; called by muse, mutect2, varscan2
- DMRT3 | c.642C>G p.P214= | Silent (SNP) | VAF 16/152 reads (11%) | catalogued as COSV99505915; called by muse, mutect2, varscan2
- DNMT3A | c.321T>G p.A107= | Silent (SNP) | VAF 27/162 reads (17%) | catalogued as COSV99262866; called by muse, mutect2, varscan2
- ELK1 | c.639C>T p.A213= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs779837119, COSV99902176; called by muse, varscan2
- ENOSF1 | c.1119C>G p.L373= (on ENST00000340116 / NM_001354066.2; = p.L339= on NM_017512.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/288 reads (13%) | catalogued as COSV99201088; called by muse, mutect2, varscan2
- FAM135B | c.2157A>C p.R719= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV99424802; called by muse, mutect2, varscan2
- FAM180A | c.474C>T p.A158= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV100647295; called by muse, mutect2, varscan2
- FSTL1 | c.588C>G p.L196= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV99820679, COSV99820738; called by muse, mutect2, varscan2
- GABRA5 | c.1002G>C p.A334= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV100165307, COSV59475836; called by muse, mutect2
- GLRA3 | c.654C>A p.P218= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs1477788774, COSV99927676; called by muse, mutect2, varscan2
- GNAO1 | c.339G>A p.R113= | Silent (SNP) | VAF 9/111 reads (8%) | catalogued as COSV99341306; called by muse, mutect2
- GPR158 | c.2295C>T p.V765= | Silent (SNP) | VAF 45/179 reads (25%) | catalogued as COSV100893732; called by muse, mutect2, varscan2
- GPR50 | c.1569T>A p.P523= | Silent (SNP) | VAF 15/243 reads (6%) | catalogued as COSV99506254; called by muse, mutect2
- GREB1 | c.3786C>G p.P1262= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV99303085; called by muse, mutect2, varscan2
- GSPT1 | c.1218C>T p.I406= (on ENST00000420576 / NM_001130007.2; = p.I544= on NM_002094.4) | Silent (SNP) | VAF 11/239 reads (5%) | catalogued as COSV101341739; called by muse, mutect2
- HERC2 | c.6429G>T p.A2143= | Silent (SNP) | VAF 28/126 reads (22%) | catalogued as COSV99874548; called by muse, mutect2, varscan2
- HIPK2 | c.1974T>C p.C658= | Silent (SNP) | VAF 10/19 reads (53%) | called by muse, mutect2
- HK2 | c.2499C>T p.L833= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV99309174; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1644G>A p.K548= | Silent (SNP) | VAF 45/275 reads (16%) | catalogued as COSV100079652; called by muse, mutect2, varscan2
- HSF4 | c.684C>T p.C228= | Silent (SNP) | VAF 22/148 reads (15%) | catalogued as COSV99263548; called by muse, mutect2, varscan2
- HYDIN | c.177C>A p.T59= | Silent (SNP) | VAF 26/98 reads (27%) | catalogued as COSV99863581; called by muse, mutect2, varscan2
- IGSF22 | c.1017G>A p.V339= | Silent (SNP) | VAF 27/132 reads (20%) | catalogued as COSV100079895; called by muse, mutect2, varscan2
- IL7R | c.753C>T p.F251= | Silent (SNP) | VAF 11/201 reads (5%) | catalogued as COSV100286336, COSV57409614; called by muse, mutect2
- IP6K3 | c.909G>T p.L303= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as COSV99539899; called by muse, mutect2, varscan2
- ITPR2 | c.3084T>C p.D1028= | Silent (SNP) | VAF 26/147 reads (18%) | catalogued as COSV101190033; called by muse, mutect2, varscan2
- ITSN1 | c.5163G>A p.P1721= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as rs144206450; called by muse, mutect2, varscan2
- KCNV2 | c.249C>G p.T83= | Silent (SNP) | VAF 51/88 reads (58%) | catalogued as COSV101172611, COSV66056029; called by muse, mutect2, varscan2
- KCTD11 | c.780G>C p.L260= (on ENST00000333751 / NM_001363642.1; = p.L221= on NM_001002914.2) | Silent (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- LATS1 | c.2784A>T p.T928= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as COSV99486153; called by muse, mutect2, varscan2
- LILRB5 | c.621G>T p.S207= | Silent (SNP) | VAF 14/168 reads (8%) | catalogued as COSV100300498; called by muse, mutect2
- MAP1A | c.6909C>T p.L2303= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV100288782; called by muse, mutect2, varscan2
- MDM4 | c.774T>A p.A258= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as rs755151417, COSV100914464; called by muse, mutect2, varscan2
- MFSD13A | c.486C>T p.L162= | Silent (SNP) | VAF 15/211 reads (7%) | catalogued as COSV99487924; called by muse, mutect2
- MICAL2 | c.159C>G p.L53= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV99817704; called by muse, mutect2, varscan2
- MME | c.1830G>A p.Q610= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as COSV100852429; called by muse, mutect2, varscan2
- MS4A8 | c.291A>G p.E97= | Silent (SNP) | VAF 45/170 reads (26%) | catalogued as COSV100282564; called by muse, mutect2, varscan2
- MUC16 | c.12300T>A p.P4100= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as COSV101200197; called by muse, mutect2, varscan2
- MUCL3 | c.1089A>G p.T363= (on ENST00000304311; = p.T1239= on NM_080870.4) | Silent (SNP) | VAF 71/140 reads (51%) | catalogued as rs1172353406, COSV100424172; called by muse, mutect2, varscan2
- MYH10 | c.105A>T p.L35= | Silent (SNP) | VAF 8/188 reads (4%) | catalogued as COSV99345480; called by muse, mutect2
- MYO1A | c.600C>A p.I200= | Silent (SNP) | VAF 6/140 reads (4%) | catalogued as COSV100270994; called by muse, mutect2
- MYO7A | c.3267C>A p.A1089= | Silent (SNP) | VAF 20/116 reads (17%) | catalogued as COSV101289167; called by muse, mutect2, varscan2
- NLRP9 | c.354C>T p.H118= | Silent (SNP) | VAF 34/189 reads (18%) | catalogued as rs1332197074, COSV60462974; called by muse, mutect2, varscan2
- NPC1L1 | c.174G>C p.L58= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as COSV99212375; called by muse, mutect2, varscan2
- NRXN2 | c.1620T>A p.G540= | Silent (SNP) | VAF 13/160 reads (8%) | catalogued as COSV99634638; called by muse, mutect2
- NTN1 | c.1590C>T p.R530= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs377128539; called by muse, mutect2, varscan2
- NUP155 | c.1854C>G p.S618= (on ENST00000231498 / NM_153485.3; = p.S559= on NM_004298.4) | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as rs73749020, COSV51528896, COSV99193375; called by muse, mutect2, varscan2
- OR2G6 | c.576G>T p.T192= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as rs142784594, COSV58575262; called by muse, mutect2, varscan2
- OR2T2 | c.42C>A p.V14= | Silent (SNP) | VAF 26/272 reads (10%) | catalogued as COSV61619363; called by muse, mutect2
- OR51E2 | c.664C>A p.R222= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as rs769497679, COSV101211353, COSV67807109; called by muse, mutect2, varscan2
- OR5A1 | c.420C>A p.T140= | Silent (SNP) | VAF 103/437 reads (24%) | catalogued as COSV100118388; called by muse, mutect2, varscan2
- PASD1 | c.795T>G p.T265= | Silent (SNP) | VAF 78/101 reads (77%) | catalogued as COSV100949420; called by muse, mutect2, varscan2
- PDCD1 | c.180G>T p.S60= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV100545443; called by muse, mutect2, varscan2
- PHF8 | c.1032A>C p.G344= (on ENST00000357988 / NM_001184896.1; = p.G308= on NM_015107.3) | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV100154363, COSV57682315; called by muse, mutect2, varscan2
- PRAMEF15 | c.978G>A p.K326= | Silent (SNP) | VAF 100/443 reads (23%) | called by muse, mutect2, varscan2
- PRKCE | c.2205G>C p.L735= | Silent (SNP) | VAF 23/165 reads (14%) | catalogued as COSV100078338; called by muse, mutect2, varscan2
- PRR27 | c.327C>T p.F109= | Silent (SNP) | VAF 24/377 reads (6%) | catalogued as COSV100748833; called by muse, mutect2
- PXK | c.1554T>C p.P518= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as rs564898479, COSV100240175; called by muse, mutect2, varscan2
- PYGB | c.1054C>A p.R352= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV99405062, COSV99405190; called by muse, mutect2, varscan2
- RBM22 | c.414G>A p.G138= | Silent (SNP) | VAF 40/99 reads (40%) | catalogued as COSV99556033; called by muse, mutect2, varscan2
- REL | c.1488G>A p.V496= | Silent (SNP) | VAF 10/160 reads (6%) | catalogued as COSV99692154; called by muse, mutect2
- RELN | c.393T>C p.S131= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV100634005; called by muse, mutect2, varscan2
- RP1 | c.153C>T p.V51= | Silent (SNP) | VAF 21/95 reads (22%) | catalogued as rs1242093722, COSV99607795; called by muse, mutect2, varscan2
- SALL4 | c.1059A>G p.L353= | Silent (SNP) | VAF 7/92 reads (8%) | catalogued as COSV99409625; called by muse, mutect2
- SDK1 | c.3033G>T p.V1011= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV101269493, COSV67381908; called by muse, mutect2, varscan2
- SEMA5B | c.1335G>A p.A445= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs1214299086, COSV99532191; called by muse, mutect2, varscan2
- SEMG2 | c.141C>T p.H47= | Silent (SNP) | VAF 12/118 reads (10%) | catalogued as COSV101034113; called by muse, mutect2, varscan2
- SERPINE1 | c.301C>T p.L101= | Silent (SNP) | VAF 67/287 reads (23%) | catalogued as COSV99776734; called by muse, mutect2, varscan2
- SIGLEC8 | c.552G>T p.G184= | Silent (SNP) | VAF 24/318 reads (8%) | catalogued as COSV58473527; called by muse, mutect2
- SLC16A4 | c.1092G>A p.K364= | Silent (SNP) | VAF 19/102 reads (19%) | catalogued as COSV100872970; called by muse, mutect2, varscan2
- SLC26A3 | c.1656T>C p.F552= | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as COSV100385125; called by muse, mutect2, varscan2
- SLC5A8 | c.195C>T p.F65= | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as COSV73310828; called by muse, mutect2, varscan2
- SMC4 | c.2718T>C p.L906= | Silent (SNP) | VAF 23/170 reads (14%) | catalogued as COSV100644063; called by muse, mutect2, varscan2
- SNAPIN | c.378G>C p.S126= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV100721820, COSV100721957; called by mutect2, varscan2
- SPEM2 | c.558G>A p.E186= | Silent (SNP) | VAF 50/129 reads (39%) | catalogued as COSV100081097; called by muse, mutect2, varscan2
- SPG11 | c.2223C>T p.A741= | Silent (SNP) | VAF 9/140 reads (6%) | catalogued as COSV99968896; called by muse, mutect2
- ST6GALNAC5 | c.498C>A p.T166= | Silent (SNP) | VAF 30/124 reads (24%) | catalogued as COSV100602812, COSV59562661; called by muse, mutect2, varscan2
- TGM5 | c.978G>A p.G326= (on ENST00000220420 / NM_201631.4; = p.G244= on NM_004245.4) | Silent (SNP) | VAF 26/130 reads (20%) | catalogued as rs891488234, COSV99589061; called by muse, mutect2, varscan2
- TIMP3 | c.183C>A p.V61= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV99831197; called by muse, mutect2, varscan2
- TPTE | c.1098G>T p.L366= (on ENST00000618007 / NM_199261.4; = p.L348= on NM_199259.4) | Silent (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2, varscan2
- TTN | c.7911T>A p.A2637= (on ENST00000591111; = p.A2591= on NM_003319.4) | Silent (SNP) | VAF 37/135 reads (27%) | catalogued as COSV100617710; called by muse, mutect2, varscan2
- UGT2B11 | c.639T>C p.N213= | Silent (SNP) | VAF 22/114 reads (19%) | catalogued as rs146629153; called by muse, mutect2
- UNC5D | c.267C>A p.G89= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV99776093; called by muse, mutect2, varscan2
- USH1C | c.840T>C p.S280= | Silent (SNP) | VAF 25/143 reads (17%) | catalogued as COSV99140325; called by muse, mutect2, varscan2
- USP6 | c.3291C>G p.V1097= | Silent (SNP) | VAF 53/154 reads (34%) | catalogued as COSV100004262; called by muse, mutect2, varscan2
- ZFP57 | c.894A>G p.P298= | Silent (SNP) | VAF 14/301 reads (5%) | catalogued as COSV100971893; called by muse, mutect2
- ZNF480 | c.1230A>G p.Q410= | Silent (SNP) | VAF 107/183 reads (58%) | catalogued as rs375086921; called by muse, mutect2, varscan2
- ZNF543 | c.1287A>G p.G429= | Silent (SNP) | VAF 53/108 reads (49%) | catalogued as COSV100386815; called by muse, mutect2, varscan2
- ZNF560 | c.2193G>T p.V731= | Silent (SNP) | VAF 29/121 reads (24%) | catalogued as COSV100038706; called by muse, mutect2, varscan2
- ZNF808 | c.252G>T p.V84= | Silent (SNP) | VAF 20/506 reads (4%) | catalogued as COSV100708021, COSV63122043; called by muse, mutect2
- ABCC9 | chr12:21801047 C>A | 3'Flank (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- AC013717.1 | c.1134+25707C>A | Intron (SNP) | VAF 13/34 reads (38%) | called by muse, varscan2
- CPLANE1 | c.*5224G>T | 3'UTR (SNP) | VAF 58/171 reads (34%) | catalogued as COSV57068321, COSV99950843; called by muse, mutect2, varscan2
- CPLANE1 | c.*4866C>G | 3'UTR (SNP) | VAF 28/117 reads (24%) | catalogued as rs772939079, COSV57070439, COSV99950844; called by muse, mutect2, varscan2
- FMN1 | c.2044-2692G>C | Intron (SNP) | VAF 10/77 reads (13%) | catalogued as COSV100568830; called by muse, mutect2, varscan2
- HERC2P3 | n.440G>T | RNA (SNP) | VAF 4/39 reads (10%) | called by mutect2, varscan2
- MIR515-2 | n.48G>A | RNA (SNP) | VAF 59/128 reads (46%) | called by muse, mutect2, varscan2
- OR2W5 | n.612C>A | RNA (SNP) | VAF 34/142 reads (24%) | called by muse, varscan2
- SERPINA5 | c.*1G>C | 3'UTR (SNP) | VAF 94/438 reads (21%) | catalogued as COSV100291683; called by muse, mutect2, varscan2
- SUGT1P4-STRA6LP | n.1432G>T | RNA (SNP) | VAF 4/36 reads (11%) | called by mutect2, varscan2
